Somatic mutation profile of tumor specimen TCGA-98-A53I-01A (aliquot TCGA-98-A53I-01A-31D-A25L-08) from TCGA case TCGA-98-A53I, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.3 years (23,502 days).
Specimen TCGA-98-A53I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c92aeda0-e669-41d2-bbce-c3429b14730f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A53I-10A (Blood Derived Normal), aliquot TCGA-98-A53I-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b93dee1a-82bc-4b33-a9da-b0592326ffcd

The open-access MAF lists 424 somatic variants for this specimen: 313 protein-altering or splice-affecting, 97 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 97, Nonsense Mutation 22, Frame Shift Del 11, Splice Site 10, RNA 4, Intron 4, 3'UTR 3, Frame Shift Ins 3, Splice Region 3, 3'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553668196, COSV100561305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- AARS1 | c.530A>C p.E177A | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933284; called by muse, mutect2, varscan2
- ACOT12 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV100296814; called by muse, mutect2, varscan2
- ADAM17 | c.1154C>G p.T385R | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176113, COSV60397536; called by muse, mutect2
- ADAM23 | c.1812C>A p.C604* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100007056; called by muse, mutect2, varscan2
- ADAMTS20 | c.5023A>G p.M1675V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV101239064; called by muse, mutect2, varscan2
- ADAMTS20 | c.2014A>G p.M672V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs745538098, COSV101239065; called by muse, mutect2, varscan2
- ADAMTS6 | c.828G>T p.L276F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101124845; called by muse, mutect2, varscan2
- ADGRG4 | c.3146C>G p.S1049* | Nonsense Mutation (SNP) | VAF 72/163 reads (44%) | catalogued as COSV99794816; called by muse, mutect2, varscan2
- ADRA2B | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101337350; called by muse, mutect2, varscan2
- AKAP11 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99213656; called by muse, mutect2, varscan2
- AKAP6 | c.1819C>G p.Q607E | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99799321; called by muse, mutect2, varscan2
- AKNA | c.2201G>C p.S734T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.225); catalogued as COSV99799921; called by muse, mutect2, varscan2
- ANK2 | c.7868C>T p.S2623F | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.387); catalogued as COSV100000403, COSV52143824; called by muse, mutect2, varscan2
- ANKRD37 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99248980; called by muse, mutect2, varscan2
- AP4B1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99870652; called by muse, mutect2, varscan2
- ARR3 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs139742233, COSV99333565; called by muse, mutect2, varscan2
- ATAD5 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV58978676; called by muse, mutect2, varscan2
- ATP13A4 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.973); catalogued as COSV99794192; called by muse, mutect2, varscan2
- ATP6V0D2 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1326853579, COSV99571482; called by muse, mutect2, varscan2
- BCL2L12 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99880948; called by muse, mutect2, varscan2
- BEND3 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs781885048; called by muse, mutect2
- BRWD3 | c.5066G>A p.R1689K | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100955809; called by muse, mutect2, varscan2
- C10orf53 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as COSV100935019; called by muse, mutect2, varscan2
- CACNA1B | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53151441, COSV99495970; called by muse, mutect2, varscan2
- CBARP | c.593T>C p.I198T (on ENST00000382477; = p.I178T on NM_152769.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99289430; called by muse, mutect2, varscan2
- CCN4 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99137000; called by muse, mutect2, varscan2
- CCNP | c.160G>T p.V54F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV99695788; called by muse, mutect2
- CCR3 | c.910G>T p.V304F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs780423426, COSV100656380, COSV62462439; called by muse, mutect2, varscan2
- CDC16 | c.900G>T p.V300= | Splice Region (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99372790; called by muse, varscan2
- CDC25B | c.571G>C p.D191H (on ENST00000245960 / NM_021873.3; = p.D177H on NM_004358.4) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99847706; called by muse, mutect2
- CDH9 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV50282457, COSV99142338; called by muse, mutect2, varscan2
- CDKN2A | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 65/138 reads (47%) | catalogued as COSV58682729; called by muse, mutect2, varscan2
- CDON | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99700977; called by muse, mutect2, varscan2
- CERCAM | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100863890; called by muse, mutect2, varscan2
- CHRD | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV52606703, COSV99200269; called by muse, mutect2
- CLC | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.208); catalogued as COSV99695564; called by muse, mutect2, varscan2
- CNTN4 | c.2698+1G>T p.X900_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100639018, COSV100639509; called by muse, mutect2, varscan2
- CNTNAP2 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663014, COSV100664094; called by muse, mutect2, varscan2
- COL11A1 | c.3337C>A p.P1113T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100615541; called by muse, varscan2
- COL12A1 | c.8138T>C p.V2713A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1465422166, COSV100485595; called by muse, mutect2
- COL15A1 | c.1963G>C p.G655R | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897525; called by muse, mutect2, varscan2
- COL4A5 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM010191, COSV100086984; called by muse, mutect2, varscan2
- COPA | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99614974; called by muse, mutect2, varscan2
- CPB1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | catalogued as COSV99294138; called by muse, mutect2, varscan2
- CPS1 | c.4129G>A p.V1377M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV99242475; called by muse, mutect2, varscan2
- CSMD1 | c.10474G>A p.A3492T (on ENST00000520002; = p.A3491T on NM_033225.6) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145346; called by muse, mutect2, varscan2
- CSMD2 | c.9682G>A p.E3228K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs891390487, COSV53954045; called by muse, mutect2, varscan2
- CSMD3 | c.7682G>T p.R2561L (on ENST00000297405 / NM_001363185.1; = p.R2457L on NM_052900.3) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs750618214, COSV52169321, COSV52276730; called by muse, varscan2
- CST8 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55671938; called by muse, mutect2, varscan2
- CTNNA2 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100559678, COSV58136648, COSV58140250; called by muse, mutect2, varscan2
- CTSE | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs371242472; called by muse, mutect2, varscan2
- CYP19A1 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.044); catalogued as rs201610075, COSV99547469; called by muse, mutect2, varscan2
- DCAF4L2 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60476518, COSV99081973; called by mutect2, varscan2
- DCAF4L2 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100150610, COSV60482891; called by muse, mutect2, varscan2
- DMD | c.5535G>T p.E1845D | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV63803013; called by muse, mutect2, varscan2
- DNAH3 | c.9230G>A p.R3077H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759911638, COSV99765758; called by muse, mutect2, varscan2
- DNAH5 | c.8299G>T p.V2767L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV99446588; called by muse, mutect2, varscan2
- DOCK10 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99288335; called by muse, mutect2
- DOCK8 | c.4004T>C p.V1335A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs763029509, COSV101209845; called by muse, mutect2, varscan2
- DPPA4 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs748055827, COSV100169292; called by muse, mutect2, varscan2
- DPY19L2 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745370120, COSV100193014, COSV61046514; called by muse, mutect2
- DSCAM | c.3851C>A p.A1284D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101259510; called by muse, mutect2, varscan2
- DST | c.20242C>T p.H6748Y (on ENST00000361203 / NM_001374722.1; = p.H4445Y on NM_015548.5) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104390737, COSV99752827; called by muse, mutect2, varscan2
- DTX4 | c.957G>C p.K319N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99915154; called by muse, mutect2, varscan2
- EDC4 | c.1732C>G p.P578A | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV100738962; called by muse, mutect2
- EDNRB | c.1330G>T p.D444Y (on ENST00000377211 / NM_001201397.1; = p.D354Y on NM_000115.5) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100526397; called by muse, mutect2, varscan2
- ERBB4 | c.3453G>A p.M1151I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100724137, COSV61517722; called by muse, mutect2, varscan2
- EZH2 | c.929A>G p.N310S (on ENST00000460911 / NM_001203247.2; = p.N315S on NM_004456.5) | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.088); catalogued as COSV100235147; called by muse, mutect2, varscan2
- FAM107B | c.56A>T p.K19I (on ENST00000378458 / NM_001320737.1; = p.K194I on NM_031453.3) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473676; called by muse, mutect2, varscan2
- FASN | c.6605G>A p.C2202Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100147507; called by muse, mutect2, varscan2
- FBLN7 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV99734764; called by muse, mutect2, varscan2
- FBXL7 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs189208873; called by muse, mutect2, varscan2
- FGD6 | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV100676434; called by muse, mutect2, varscan2
- FKBP14 | c.605G>T p.R202I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99767062; called by muse, mutect2, varscan2
- FKBP15 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53040361, COSV99438326; called by muse, mutect2, varscan2
- FRMPD1 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100733507; called by muse, mutect2, varscan2
- FYB2 | c.1943G>A p.R648K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100599360, COSV58588460; called by muse, varscan2
- FYCO1 | c.3945-1G>C p.X1315_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as CS1410338, COSV99945341; called by muse, mutect2, varscan2
- G2E3 | c.1495A>T p.I499F | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.121); catalogued as COSV99249431; called by muse, mutect2
- GALC | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99729236; called by muse, mutect2
- GALNT17 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100352890; called by muse, mutect2, varscan2
- GANC | c.776A>T p.Y259F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | PolyPhen benign (0.009); catalogued as COSV100530775; called by muse, mutect2, varscan2
- GAS2L1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53330876, COSV99329447; called by muse, mutect2, varscan2
- GGTLC1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV99600484; called by muse, mutect2, varscan2
- GHSR | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV99576794; called by muse, mutect2, varscan2
- GKN2 | c.497C>G p.A166G | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs769336189, COSV100187731; called by muse, mutect2, varscan2
- GLCCI1 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56200386, COSV56204331, COSV99780200; called by muse, mutect2, varscan2
- GLRA3 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56863922, COSV99927205; called by muse, mutect2, varscan2
- GMEB1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99603033; called by muse, mutect2, varscan2
- GPR158 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100892981; called by muse, mutect2, varscan2
- GRIA2 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.359); catalogued as COSV99643496; called by muse, varscan2
- GRIN2B | c.3170G>C p.R1057P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV101662966; called by muse, mutect2, varscan2
- GRM7 | c.1362T>A p.N454K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as COSV100735960; called by muse, mutect2
- GRM8 | c.1131del p.N378Tfs*4 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as COSV100285476; called by mutect2, pindel, varscan2
- HMCN1 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99625904; called by muse, mutect2, varscan2
- HMCN1 | c.4918A>G p.M1640V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1004795910, COSV99625906; called by muse, mutect2, varscan2
- HMCN1 | c.9334G>C p.G3112R | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99625909; called by muse, mutect2, varscan2
- HMCN1 | c.9335G>T p.G3112V | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54929909, COSV99625911; called by muse, mutect2, varscan2
- HMGCR | c.781-1G>C p.X261_splice | Splice Site (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99843090; called by muse, mutect2, varscan2
- HMGN3 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as COSV99245560; called by muse, mutect2, varscan2
- HSPA14 | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 35/140 reads (25%) | catalogued as COSV101000647; called by muse, mutect2, varscan2
- HTR1B | c.1153C>A p.R385S | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100885360; called by muse, mutect2, varscan2
- HTR5A | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV55285281, COSV99839526; called by muse, mutect2, varscan2
- ICE1 | c.3735A>T p.L1245F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99664110; called by muse, mutect2, varscan2
- IFT122 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs749466359, COSV56207357; called by muse, mutect2, varscan2
- IL1A | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.617); catalogued as COSV54519136, COSV99641295; called by muse, mutect2, varscan2
- ILVBL | c.338-1G>A p.X113_splice | Splice Site (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99654666; called by muse, mutect2, varscan2
- INSC | c.927C>A p.C309* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV101088904, COSV65408654; called by muse, mutect2
- INSRR | c.3742G>T p.E1248* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100947277; called by muse, mutect2
- ITGA5 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53218623, COSV99516441; called by muse, mutect2, varscan2
- ITPRIPL2 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101198159; called by muse, mutect2, varscan2
- KAT2A | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99863443; called by muse, mutect2, varscan2
- KCNA7 | c.1342C>G p.P448A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99671857; called by muse, varscan2
- KCNB1 | c.2293C>G p.Q765E | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100870417; called by muse, mutect2, varscan2
- KDM3B | c.3014A>G p.E1005G | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069308; called by muse, mutect2, varscan2
- KDM5C | c.1616C>A p.S539* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100948908; called by muse, mutect2, varscan2
- KHK | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV99565055; called by muse, mutect2, varscan2
- KIF3A | c.1326A>T p.E442D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV101109278, COSV66415507; called by muse, mutect2, varscan2
- KIF4B | c.2958G>T p.E986D | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV70529311; called by muse, mutect2, varscan2
- KIF5B | c.242T>G p.I81R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100191617, COSV100192139; called by muse, mutect2, varscan2
- KLHL40 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99825389; called by muse, mutect2, varscan2
- KNDC1 | c.2147C>A p.S716Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV100463834; called by muse, mutect2, varscan2
- LAMB4 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs898724490, COSV52726350, COSV99063904; called by muse, mutect2, varscan2
- LANCL2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV99634578; called by muse, mutect2, varscan2
- LCT | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928916; called by muse, mutect2, varscan2
- LCT | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99928917; called by muse, mutect2, varscan2
- LENG1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV99651620; called by muse, mutect2, varscan2
- LHCGR | c.1301A>T p.Q434L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99683354; called by muse, mutect2, varscan2
- LMAN1L | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100547620; called by muse, mutect2, varscan2
- LMTK2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs368088478; called by muse, mutect2, varscan2
- LMX1A | c.726G>A p.W242* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99671863; called by muse, mutect2, varscan2
- LRP2 | c.5875C>T p.Q1959* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as COSV55543473, COSV99787148; called by muse, mutect2, varscan2
- LRP2 | c.4495G>T p.D1499Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201993572, COSV55569755, COSV99787150; called by muse, mutect2, varscan2
- LRRC1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs763233291, COSV63828010; called by muse, mutect2, varscan2
- LRRIQ4 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100540143, COSV61619163; called by muse, mutect2, varscan2
- LRRK2 | c.2632A>T p.I878F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as COSV100109558; called by muse, mutect2, varscan2
- LTK | c.2347-2A>G p.X783_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as rs570072922, COSV99540688; called by muse, mutect2, varscan2
- LVRN | c.1515+2T>A p.X505_splice | Splice Site (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100773377; called by muse, mutect2, varscan2
- MACF1 | c.9604A>G p.K3202E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99242466; called by muse, mutect2, varscan2
- MAGEA12 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1556833380, COSV100756838; called by muse, mutect2, varscan2
- MAGEA6 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100262725; called by muse, mutect2, varscan2
- MAGEC3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.665); catalogued as rs1233217814, COSV100025064; called by muse, mutect2, varscan2
- MALT1 | c.2378A>G p.H793R | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs756463496, COSV100618630; called by muse, mutect2, varscan2
- MARCHF11 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100197580, COSV60131250; called by muse, mutect2, varscan2
- MC4R | c.671del p.K224Rfs*18 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | catalogued as COSV55351758; called by mutect2, pindel, varscan2
- MCCC2 | c.1020T>A p.D340E | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100040025; called by muse, mutect2, varscan2
- MDGA2 | c.1695T>A p.Y565* (on ENST00000399232 / NM_001113498.2; = p.Y267* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 80/275 reads (29%) | catalogued as COSV100636579; called by muse, varscan2
- MDN1 | c.4651C>T p.R1551C | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs543829019, COSV101020944; called by muse, mutect2, varscan2
- MED12L | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99852054; called by muse, mutect2, varscan2
- MEST | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56228257; called by muse, mutect2, varscan2
- MFSD3 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1053123306, COSV100020351; called by muse, mutect2, varscan2
- MFSD6 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV99855092; called by muse, mutect2, varscan2
- MMP8 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs562264919, COSV52632495; called by muse, mutect2, varscan2
- MRPL14 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.545); catalogued as rs940325622, COSV100921031; called by muse, mutect2, varscan2
- MRPS30 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1356850887, COSV99138130; called by muse, mutect2, varscan2
- MSTN | c.589A>C p.N197H | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV99640585; called by muse, mutect2, varscan2
- MUC16 | c.13114A>T p.N4372Y | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.084); catalogued as COSV101198829; called by muse, mutect2, varscan2
- MUC3A | c.8029T>A p.F2677I | Missense Mutation (SNP) | VAF 32/814 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV100114203; called by muse, mutect2
- MUC5B | c.8954C>G p.S2985C | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs1262849143, COSV101500131; called by muse, mutect2, varscan2
- MYBPC1 | c.2734C>T p.Q912* (on ENST00000550270 / NM_206820.2; = p.Q919* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 51/229 reads (22%) | catalogued as COSV100637830; called by muse, mutect2, varscan2
- NAP1L3 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100220241; called by muse, mutect2, varscan2
- NCAPH | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.334); catalogued as COSV99545644; called by muse, mutect2, varscan2
- NEFL | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99647883; called by muse, mutect2, varscan2
- NEU4 | c.1423del p.D475Tfs*89 (on ENST00000391969 / NM_001167602.3; = p.D487Tfs*89 on NM_080741.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV57991884; called by pindel, varscan2
- NLRP6 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100380973; called by muse, mutect2, varscan2
- NOMO2 | c.2102C>A p.S701Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100395601; called by mutect2, varscan2
- NPAS3 | c.152T>G p.L51W (on ENST00000356141 / NM_001164749.2; = p.L21W on NM_022123.3) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100386733; called by muse, mutect2, varscan2
- NR1H4 | c.277C>A p.P93T (on ENST00000551379 / NM_001206993.2; = p.P83T on NM_005123.4) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.06); catalogued as COSV99500218; called by muse, mutect2, varscan2
- NSD3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.551); catalogued as rs1193485020, COSV100388532; called by muse, mutect2, varscan2
- NSUN6 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV101045461; called by muse, mutect2, varscan2
- OR10Z1 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 124/346 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100778963; called by muse, mutect2, varscan2
- OR2M2 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 184/374 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62897784; called by muse, mutect2, varscan2
- OR56B4 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs775294260, COSV100337639, COSV100337689, COSV57204111; called by muse, mutect2, varscan2
- OR5AU1 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100436095, COSV58615564; called by muse, mutect2, varscan2
- OR5B21 | c.870G>T p.R290S | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100835117; called by muse, mutect2, varscan2
- OR5L1 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV100449968; called by muse, mutect2, varscan2
- OR6S1 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV100289308, COSV57838755; called by muse, mutect2, varscan2
- OR8H2 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100542208, COSV57945488; called by muse, mutect2, varscan2
- OR8I2 | c.489A>G p.I163M | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV100135925; called by muse, mutect2, varscan2
- OSMR | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV99952869; called by muse, mutect2, varscan2
- OTOR | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV99856140; called by muse, mutect2, varscan2
- OTUD7A | c.1795A>G p.T599A (on ENST00000307050 / NM_001382637.1; = p.T592A on NM_130901.3) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100192081; called by muse, mutect2, varscan2
- PAPOLG | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99474536; called by muse, mutect2, varscan2
- PAPPA2 | c.222G>T p.R74S | Missense Mutation (SNP) | VAF 100/344 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV100866631, COSV62774343; called by muse, mutect2, varscan2
- PCDHB15 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554291991, COSV99178852; called by muse, mutect2, varscan2
- PCDHB7 | c.278A>T p.E93V | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99176374; called by muse, mutect2, varscan2
- PCDHGA4 | c.2514+7C>A | Splice Region (SNP) | VAF 18/65 reads (28%) | catalogued as rs1335077514; called by muse, mutect2, varscan2
- PCDHGA8 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV99533656; called by muse, mutect2, varscan2
- PIAS2 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765295036, COSV100245106; called by muse, mutect2, varscan2
- PIAS2 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100245110; called by muse, mutect2, varscan2
- PKHD1 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100581891; called by muse, mutect2, varscan2
- PKHD1L1 | c.10741T>A p.F3581I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV101005702; called by muse, mutect2, varscan2
- PLOD3 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749637576, COSV99777738, COSV99777893; called by muse, mutect2, varscan2
- PLS1 | c.1506-1G>T p.X502_splice | Splice Site (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100538004; called by muse, mutect2, varscan2
- PLXND1 | c.315C>G p.H105Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100139254; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1060+2T>C p.X354_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as rs773230317, COSV100982418; called by muse, mutect2, varscan2
- POM121L12 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777263049, COSV68693248; called by muse, mutect2, varscan2
- POM121L12 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101374887, COSV68693476; called by muse, mutect2, varscan2
- POTEA | c.1248C>A p.N416K (on ENST00000519951 / NM_001005365.2; = p.N370K on NM_001002920.1) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as rs746892979; called by muse, mutect2, varscan2
- PRKAR1B | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100816574; called by mutect2, varscan2
- PRKCE | c.2045A>G p.K682R | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100077186; called by muse, mutect2, varscan2
- PRL | c.29-2A>T p.X10_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100122960; called by muse, varscan2
- PROS1 | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV101260335; called by muse, mutect2, varscan2
- PROX1 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1476156893, COSV99798895; called by muse, mutect2, varscan2
- PRPF31 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100319897; called by muse, mutect2, varscan2
- PRTG | c.3044A>T p.E1015V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101221326; called by muse, mutect2, varscan2
- PTGER3 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1302193773, COSV100138502, COSV60695422; called by muse, mutect2, varscan2
- PXDN | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV53239055; called by muse, mutect2, varscan2
- RAB25 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs775394870, COSV100737303; called by muse, mutect2, varscan2
- RALGAPA2 | c.5498A>G p.Y1833C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371607956; called by muse, mutect2, varscan2
- RBP3 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1158993702; called by muse, mutect2, varscan2
- REG1B | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV100521298; called by mutect2, varscan2
- REG1B | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 43/202 reads (21%) | catalogued as COSV100521301; called by muse, mutect2, varscan2
- RET | c.2567G>T p.W856L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100392831; called by muse, mutect2, varscan2
- SALL1 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs752678352, COSV99172070; called by muse, mutect2, varscan2
- SALL3 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101609958, COSV73305909; called by muse, mutect2, varscan2
- SAMD9 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV101180158; called by muse, mutect2, varscan2
- SBSN | c.1588G>T p.A530S (on ENST00000452271 / NM_001166034.2; = p.A187S on NM_198538.4) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV101510051; called by muse, mutect2, varscan2
- SCN2A | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51843281, COSV99330656; called by muse, mutect2, varscan2
- SCN5A | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100028300, COSV60067184; called by muse, mutect2, varscan2
- SEMA6C | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766594931, COSV59001420; called by muse, mutect2, varscan2
- SEPSECS | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100258739; called by muse, mutect2, varscan2
- SIGLEC15 | c.956G>C p.R319P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV101248703, COSV101248769; called by muse, mutect2, varscan2
- SLC16A10 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920830; called by muse, mutect2, varscan2
- SLC19A3 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs763445769, COSV99295732; called by muse, mutect2, varscan2
- SLC39A10 | c.1748C>G p.T583R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100660555; called by muse, mutect2, varscan2
- SLC4A9 | c.431A>G p.D144G (on ENST00000507527 / NM_001258428.2; = p.D120G on NM_031467.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50189991; called by muse, mutect2
- SLC5A2 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100393076; called by muse, mutect2, varscan2
- SMC4 | c.3233T>G p.L1078R | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV100557456; called by muse, mutect2
- SNX29 | c.2216A>T p.Q739L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100027653; called by muse, mutect2
- SON | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV99277344; called by muse, mutect2, varscan2
- SORCS3 | c.1318A>C p.S440R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100864797; called by muse, mutect2, varscan2
- SPTAN1 | c.6716G>C p.G2239A | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100823354; called by muse, mutect2, varscan2
- STAM | c.1048A>T p.I350F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV101092209; called by muse, mutect2, varscan2
- STRAP | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV50308943; called by muse, mutect2, varscan2
- SYNPO | c.1154G>C p.G385A (on ENST00000394243 / NM_001166208.2; = p.G141A on NM_007286.6) | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as COSV100302002; called by muse, mutect2, varscan2
- TENM1 | c.6176C>G p.P2059R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100949422; called by muse, mutect2, varscan2
- TENM1 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV100948980, COSV100949424; called by muse, mutect2, varscan2
- TEX15 | c.2824G>A p.G942R (on ENST00000256246; = p.G1325R on NM_001350162.2) | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.022); catalogued as rs780607690, COSV99820969; called by muse, mutect2, varscan2
- TGFB1I1 | c.608G>C p.S203T (on ENST00000394863 / NM_001042454.3; = p.S186T on NM_015927.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV100690957; called by muse, mutect2, varscan2
- TGIF2LX | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as COSV99383225; called by muse, mutect2, varscan2
- TGM6 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs371408722; called by muse, mutect2, varscan2
- TGM6 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.293); catalogued as COSV99171718; called by muse, mutect2, varscan2
- THSD7A | c.4909C>A p.Q1637K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV101349163; called by muse, mutect2, varscan2
- THSD7A | c.1848C>A p.C616* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV101448581; called by muse, mutect2, varscan2
- TIAM1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99733734; called by muse, mutect2, varscan2
- TMC4 | c.1819C>T p.L607F (on ENST00000617472 / NM_001145303.3; = p.L601F on NM_144686.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.106); catalogued as COSV99713756; called by muse, mutect2, varscan2
- TMEM126A | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as COSV99476164; called by muse, mutect2, varscan2
- TMEM132D | c.2245C>A p.P749T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.672); catalogued as COSV101242632, COSV67158689; called by muse, mutect2, varscan2
- TMEM8B | c.1384G>T p.G462* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100941568; called by muse, mutect2, varscan2
- TMEM8B | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100941569; called by muse, mutect2, varscan2
- TMTC1 | c.535G>T p.A179S (on ENST00000539277 / NM_001193451.2; = p.A71S on NM_175861.3) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV99759086; called by muse, mutect2
- TNIP3 | c.609+1G>T p.X203_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as rs938654865, COSV50247051, COSV99284370; called by muse, mutect2, varscan2
- TNN | c.3414G>T p.K1138N | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV99511387; called by muse, mutect2, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53I11 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV100370835; called by muse, mutect2, varscan2
- TP63 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051829008, COSV53198047; called by muse, mutect2, varscan2
- TPPP3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370550940; called by muse, mutect2, varscan2
- TRAT1 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV55469483; called by muse, mutect2, varscan2
- TRAT1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs138588985, COSV99849132; called by muse, mutect2, varscan2
- TRIM27 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV101019251; called by muse, mutect2, varscan2
- TRIM58 | c.893C>A p.A298D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV100824951; called by muse, mutect2, varscan2
- TRMT1 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1465542223, COSV99317038; called by muse, mutect2, varscan2
- TSPOAP1 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99270423; called by muse, mutect2, varscan2
- TTN | c.95242C>A p.P31748T (on ENST00000591111; = p.P24324T on NM_003319.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | PolyPhen benign (0.43); catalogued as COSV100600666; called by muse, mutect2
- TTN | c.84047C>A p.P28016Q (on ENST00000591111; = p.P20592Q on NM_003319.4) | Missense Mutation (SNP) | VAF 40/156 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV100600667; called by muse, mutect2, varscan2
- TTN | c.80585G>A p.G26862E (on ENST00000591111; = p.G19438E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | PolyPhen benign (0.005); catalogued as rs1222429807, COSV100600670; called by muse, mutect2, varscan2
- TTN | c.70627C>A p.L23543M (on ENST00000591111; = p.L16119M on NM_003319.4) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | PolyPhen possibly damaging (0.859); catalogued as COSV100600673; called by muse, mutect2, varscan2
- TTN | c.43604G>C p.W14535S (on ENST00000591111; = p.W7111S on NM_003319.4) | Missense Mutation (SNP) | VAF 52/223 reads (23%) | PolyPhen probably damaging (0.998); catalogued as CM1514593, COSV100600683, COSV99045771; called by muse, mutect2, varscan2
- UBXN10 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100907753; called by muse, mutect2, varscan2
- UGT2B11 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV101485227; called by muse, mutect2, varscan2
- USP31 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99564820; called by muse, mutect2, varscan2
- USP42 | c.319C>A p.H107N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100084088; called by muse, mutect2, varscan2
- USP42 | c.3865G>A p.G1289R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs561480931, COSV100084091; called by muse, mutect2, varscan2
- VCPIP1 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100125436; called by muse, mutect2, varscan2
- VPS16 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs750104307, COSV100988343; called by muse, mutect2, varscan2
- VSTM2A | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100172980; called by muse, mutect2, varscan2
- WDR33 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100459732; called by muse, mutect2, varscan2
- WDR76 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99776194; called by muse, mutect2, varscan2
- WIF1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99682672; called by muse, mutect2, varscan2
- YY1AP1 | c.875T>C p.L292P (on ENST00000295566 / NM_139118.2; = p.L215P on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55119864, COSV99803667; called by muse, mutect2, varscan2
- ZDHHC23 | c.873G>T p.W291C | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100362073; called by muse, mutect2, varscan2
- ZIC1 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.885); catalogued as COSV99291677; called by muse, mutect2, varscan2
- ZNF335 | c.1330C>G p.R444G | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as rs151210181, COSV100532784; called by muse, mutect2, varscan2
- ZNF440 | c.192G>A p.R64= | Splice Region (SNP) | VAF 33/156 reads (21%) | catalogued as COSV100407438; called by muse, mutect2, varscan2
- ZNF492 | c.1257A>C p.K419N | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101513962, COSV71761760; called by muse, mutect2, varscan2
- ZNF587 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 31/160 reads (19%) | catalogued as COSV100299357; called by muse, mutect2, varscan2
- ZNF595 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV100227520; called by muse, mutect2, varscan2
- ZNF639 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100418395; called by muse, mutect2, varscan2
- ZNF804B | c.3164T>C p.L1055S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100302533; called by muse, mutect2, varscan2
- ZSWIM3 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54851226; called by muse, mutect2, varscan2
- ZSWIM4 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99584618; called by muse, mutect2, varscan2
- AKAP9 | c.10364_10381del p.L3455_L3460del (on ENST00000359028; = p.L3431_L3436del on NM_005751.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- CAND2 | c.1740del p.T581Lfs*7 (on ENST00000456430 / NM_001162499.2; = p.T488Lfs*7 on NM_012298.3) | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- CCDC141 | c.3270del p.I1090Mfs*4 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- CSMD2 | c.6236C>A p.S2079Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.059); called by muse, mutect2
- GABRG1 | c.108del p.D37Ifs*11 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | called by mutect2, pindel, varscan2
- IGHV1-2 | c.8G>C p.W3S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- INO80 | c.2796G>T p.W932C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- LGR6 | c.977del p.G326Afs*8 (on ENST00000367278 / NM_001017403.1; = p.G274Afs*8 on NM_021636.3) | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- LRRC3B | c.497_498del p.T166Sfs*7 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- MRC1 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAPPA2 | c.2328del p.T777Lfs*31 | Frame Shift Del (DEL) | VAF 61/251 reads (24%) | called by pindel, varscan2
- PAPPA2 | c.2330C>A p.T777N | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PHC2 | c.1621_1626del p.G541_N542del (on ENST00000257118 / NM_198040.2; = p.G6_N7del on NM_004427.4) | In Frame Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- PPP4R4 | c.1890del p.V632* | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- PRKCB | c.1608dup p.G537Wfs*6 | Frame Shift Ins (INS) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- TTN | c.26359dup p.T8787Nfs*17 (on ENST00000591111; = p.T7860Nfs*17 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- YTHDF3 | c.767del p.G256Afs*15 | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- ZNF26 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF408 | c.10dup p.A4Gfs*121 | Frame Shift Ins (INS) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- ADCY2 | c.2025C>A p.R675= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as COSV100602159; called by muse, mutect2, varscan2
- ADGRB3 | c.2499G>T p.T833= | Silent (SNP) | VAF 109/228 reads (48%) | catalogued as COSV99484152; called by muse, mutect2, varscan2
- ALDH2 | c.534G>T p.V178= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99922786; called by muse, mutect2, varscan2
- ARF6 | c.471C>G p.T157= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs138905564; called by muse, mutect2
- ATP13A4 | c.2475T>A p.S825= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as COSV100710182; called by muse, mutect2
- ATP2A1 | c.312G>A p.V104= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs1281685262, COSV100837146; called by muse, mutect2, varscan2
- ATP8B4 | c.543T>C p.V181= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99464346; called by muse, mutect2, varscan2
- BIRC2 | c.252C>T p.F84= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs776440324, COSV99926594; called by muse, mutect2, varscan2
- BRINP2 | c.2172G>A p.R724= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as COSV64178522; called by muse, mutect2, varscan2
- C5AR1 | c.390C>T p.I130= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV100753962; called by muse, mutect2, varscan2
- CARD6 | c.2193C>T p.S731= | Silent (SNP) | VAF 193/411 reads (47%) | catalogued as COSV99620481; called by muse, mutect2, varscan2
- CCDC88A | c.2136T>C p.S712= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99709968; called by muse, mutect2
- CD180 | c.1707G>A p.Q569= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99842150; called by muse, mutect2, varscan2
- CDC6 | c.801G>A p.L267= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1486499373, COSV99266508; called by muse, mutect2, varscan2
- CETN1 | c.252C>T p.I84= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100511193; called by muse, mutect2, varscan2
- COBL | c.2328G>A p.V776= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99471761; called by muse, mutect2, varscan2
- COL6A3 | c.507T>C p.D169= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as rs1352046046, COSV99796745; called by muse, mutect2, varscan2
- CREB3L2 | c.480G>C p.L160= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100381713; called by muse, mutect2
- CREB3L3 | c.1032C>T p.P344= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99313964; called by muse, mutect2, varscan2
- CSMD2 | c.9681C>G p.S3227= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99587365; called by muse, mutect2, varscan2
- CTNNA2 | c.909G>T p.L303= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV100782370; called by muse, varscan2
- CTTNBP2 | c.1824C>T p.S608= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99353377; called by muse, mutect2, varscan2
- CXCR6 | c.138G>T p.L46= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV99945343; called by muse, mutect2, varscan2
- CYP19A1 | c.66T>A p.P22= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs780440634, COSV99547470; called by muse, mutect2, varscan2
- DAAM2 | c.3114G>A p.K1038= (on ENST00000274867 / NM_001201427.2; = p.K1037= on NM_015345.3) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99224945; called by muse, mutect2, varscan2
- DDR2 | c.1626C>T p.A542= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs753375784, COSV100906287; called by muse, mutect2, varscan2
- FAT3 | c.3141T>A p.A1047= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99963425; called by muse, mutect2, varscan2
- FLNA | c.2112G>A p.K704= | Silent (SNP) | VAF 70/127 reads (55%) | catalogued as rs1557178670, COSV100774428; ClinVar: likely benign; called by muse, mutect2, varscan2
- FUT8 | c.699T>A p.I233= (on ENST00000360689 / NM_001371534.1; = p.I70= on NM_004480.4) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100651202; called by muse, mutect2, varscan2
- GAB4 | c.12G>A p.P4= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1167981055, COSV101271915; called by muse, mutect2, varscan2
- GPR171 | c.195G>T p.L65= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as COSV99852057; called by muse, mutect2
- GRM3 | c.999C>T p.F333= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100862282, COSV64469091; called by muse, mutect2, varscan2
- GTF3C2 | c.616C>T p.L206= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99272364; called by muse, mutect2, varscan2
- HEPH | c.1563C>T p.V521= (on ENST00000343002; = p.V254= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100294364, COSV57958868; called by muse, mutect2, varscan2
- HGD | c.654C>A p.A218= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as COSV99380764; called by muse, mutect2, varscan2
- HGS | c.435C>T p.F145= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV100230318; called by muse, mutect2, varscan2
- IFI44 | c.1203A>G p.V401= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs1414859756, COSV100877287; called by muse, mutect2, varscan2
- IFT140 | c.1146G>T p.T382= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV101276308; called by muse, mutect2, varscan2
- IGKV1-9 | c.153T>A p.I51= | Silent (SNP) | VAF 61/283 reads (22%) | catalogued as rs557257060; called by muse, mutect2, varscan2
- IMPG1 | c.1735C>T p.L579= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV100886238; called by muse, mutect2, varscan2
- IMPG2 | c.196C>T p.L66= | Silent (SNP) | VAF 55/308 reads (18%) | catalogued as COSV99515075; called by muse, mutect2, varscan2
- INSC | c.558A>T p.L186= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV101088901; called by muse, mutect2, varscan2
- INSRR | c.3741G>A p.Q1247= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100947279, COSV100947453, COSV100947497; called by muse, mutect2
- KIF1B | c.21G>A p.K7= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99822800; called by muse, mutect2, varscan2
- KY | c.1299C>A p.L433= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV101414958; called by muse, mutect2, varscan2
- LAMA5 | c.6684G>A p.E2228= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV53361311, COSV99438706; called by muse, mutect2, varscan2
- LENG1 | c.264A>T p.G88= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV99651619; called by muse, mutect2, varscan2
- LMBRD2 | c.630T>C p.P210= | Silent (SNP) | VAF 32/187 reads (17%) | catalogued as COSV99682664; called by muse, mutect2, varscan2
- LMX1A | c.828C>T p.N276= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs1216976452, COSV99671862; called by muse, mutect2, varscan2
- LRP2 | c.10353A>T p.P3451= | Silent (SNP) | VAF 63/265 reads (24%) | catalogued as rs1558997777, COSV99787146; called by muse, mutect2, varscan2
- LRP2 | c.4494G>T p.T1498= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1287160156, COSV55548536, COSV99787153; called by muse, mutect2, varscan2
- LRRIQ1 | c.3213G>A p.L1071= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs532455094, COSV101280633; called by mutect2, varscan2
- MAGEB6 | c.351A>C p.A117= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100983690; called by muse, mutect2, varscan2
- MANSC1 | c.537A>T p.S179= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as COSV101115776; called by muse, mutect2, varscan2
- MAST4 | c.5775C>T p.S1925= (on ENST00000403625 / NM_001164664.2; = p.S1736= on NM_015183.3) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs752262062, COSV99843359; called by muse, mutect2
- MFSD3 | c.768G>T p.V256= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV100020350; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1611G>A p.P537= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as rs750095694, COSV100186622; called by muse, mutect2, varscan2
- MSR1 | c.912T>A p.L304= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100026787; called by muse, mutect2
- MTREX | c.234G>A p.K78= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV100043719, COSV57928718; called by muse, mutect2, varscan2
- MYOF | c.5256G>A p.Q1752= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as rs772814311, COSV63699873; called by muse, mutect2, varscan2
- N4BP1 | c.1401A>C p.P467= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV99284925; called by muse, mutect2, varscan2
- NAMPT | c.732A>T p.A244= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV99747727; called by muse, mutect2, varscan2
- NARF | c.279G>A p.V93= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as COSV100559613; called by muse, mutect2, varscan2
- NATD1 | c.285C>T p.I95= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV101204695; called by muse, mutect2, varscan2
- NPAP1 | c.966C>A p.R322= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100274973; called by muse, mutect2, varscan2
- NRF1 | c.72G>T p.V24= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV99781650; called by muse, mutect2, varscan2
- NTRK1 | c.1224G>T p.V408= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100693202; called by muse, mutect2, varscan2
- OR51B4 | c.531C>A p.L177= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100970891; called by muse, mutect2, varscan2
- PI4KA | c.4803C>T p.A1601= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs376032431; called by muse, mutect2
- PIK3R5 | c.237C>A p.T79= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- PKHD1L1 | c.2646T>G p.T882= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV101005699, COSV101006800; called by muse, mutect2, varscan2
- PPTC7 | c.861A>T p.G287= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV100845683; called by muse, mutect2, varscan2
- PRAMEF15 | c.384C>T p.L128= | Silent (SNP) | VAF 41/241 reads (17%) | catalogued as rs1481758454; called by muse, mutect2, varscan2
- RBP3 | c.1644C>G p.A548= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.288A>G p.R96= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100653989; called by muse, mutect2, varscan2
- SIX2 | c.294G>T p.L98= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100284099; called by muse, mutect2, varscan2
- SLC4A11 | c.684C>T p.H228= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs750441626, COSV101195914; called by muse, mutect2, varscan2
- SLC4A3 | c.2427C>T p.A809= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs1178659992, COSV56094903; called by muse, mutect2, varscan2
- SLITRK3 | c.1183C>A p.R395= | Silent (SNP) | VAF 50/307 reads (16%) | catalogued as rs768253569, COSV53848946, COSV99578768; called by muse, mutect2, varscan2
- SLITRK4 | c.552T>C p.D184= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV100567219; called by muse, mutect2, varscan2
- SPTA1 | c.2793A>G p.E931= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as COSV100934603, COSV63749501; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.186G>T p.V62= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV59130016, COSV59130291; called by muse, mutect2, varscan2
- SYNE1 | c.9921C>T p.C3307= (on ENST00000367255 / NM_182961.4; = p.C3314= on NM_033071.3) | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV99557071; called by muse, mutect2, varscan2
- TCHP | c.1011G>A p.Q337= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100452526; called by muse, mutect2, varscan2
- TMEM100 | c.306C>T p.S102= | Silent (SNP) | VAF 36/170 reads (21%) | catalogued as COSV70118089; called by muse, mutect2, varscan2
- TNIK | c.249T>A p.A83= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV99455893; called by muse, mutect2, varscan2
- TOPBP1 | c.3207G>A p.E1069= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs1321702452, COSV99605052; called by muse, mutect2, varscan2
- TPTE | c.510G>T p.L170= (on ENST00000618007 / NM_199261.4; = p.L152= on NM_199259.4) | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as rs766815317; called by muse, mutect2, varscan2
- TRAV1-2 | c.168T>C p.A56= | Silent (SNP) | VAF 44/187 reads (24%) | called by muse, mutect2, varscan2
- TRIM58 | c.894C>G p.A298= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100824952; called by muse, mutect2, varscan2
- TRPM5 | c.2676G>A p.Q892= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99329787; called by muse, mutect2, varscan2
- TTN | c.47226G>A p.K15742= (on ENST00000591111; = p.K8318= on NM_003319.4) | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100600680, COSV59891046; called by muse, mutect2, varscan2
- TTN | c.43920C>T p.T14640= (on ENST00000591111; = p.T7216= on NM_003319.4) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs547682223, COSV100600681; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.21159G>A p.R7053= (on ENST00000591111; = p.R6126= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100600686, COSV59882485; called by muse, mutect2, varscan2
- TTN | c.19935A>G p.G6645= (on ENST00000591111; = p.G5718= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100600687; called by muse, mutect2, varscan2
- ZNF197 | c.561C>G p.A187= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV100482023, COSV60360562; called by muse, mutect2, varscan2
- ZNF75D | c.978A>T p.V326= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV100883606; called by muse, mutect2, varscan2
- ABTB1 | c.*149G>A | 3'UTR (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99229660; called by muse, mutect2
- AC073310.1 | n.647C>T | RNA (SNP) | VAF 39/155 reads (25%) | catalogued as rs377647044; called by muse, mutect2, varscan2
- AC244258.1 | n.441A>T | RNA (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967815 A>T | 3'Flank (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100523950; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2326G>T | Intron (SNP) | VAF 41/214 reads (19%) | catalogued as COSV99834718; called by muse, mutect2, varscan2
- DLG2 | c.205-65534G>T | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99713511; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445866 G>C | 3'Flank (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- FBLN1 | c.1698-11313C>G | Intron (SNP) | VAF 21/78 reads (27%) | catalogued as rs748995133, COSV99410233; called by muse, mutect2, varscan2
- MIR325 | n.24G>T | RNA (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- NDUFS5 | c.*2C>A | 3'UTR (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100880427; called by muse, varscan2
- RBPMS | c.528+4933A>T | Intron (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99823723; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791711 C>G | 3'Flank (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- SNORD115-26 | n.46C>T | RNA (SNP) | VAF 47/242 reads (19%) | catalogued as rs1276197479; called by muse, mutect2, varscan2
- VNN3 | c.*602C>G | 3'UTR (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99258121, COSV99258503; called by muse, mutect2, varscan2
